Somatic mutation profile of tumor specimen TCGA-15-0742-01A (aliquot TCGA-15-0742-01A-01W-0348-08) from TCGA case TCGA-15-0742, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.8 years (24,050 days).
Specimen TCGA-15-0742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97d478cc-28cf-4777-93e0-7a0cb1a5599c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-15-0742-10A (Blood Derived Normal), aliquot TCGA-15-0742-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/927c2f24-7d49-4532-9e3a-82319af8b926

The open-access MAF lists 82 somatic variants for this specimen: 72 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 9, Frame Shift Ins 9, Nonsense Mutation 6, Splice Site 1, In Frame Del 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IMPG1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 340/397 reads (86%) | catalogued as rs200651043, COSV64054288; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 36/268 reads (13%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NOTCH2 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 46/1128 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781957465, COSV56699628; ClinVar: likely pathogenic; called by muse, mutect2
- C2CD2 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs571197268, COSV61599928; called by muse, mutect2, varscan2
- CARD16 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 1477/3477 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV65213259; called by muse, mutect2, varscan2
- CCDC158 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 144/278 reads (52%) | catalogued as rs372875892, COSV66356817; called by muse, mutect2, varscan2
- CCDC18 | c.2356G>A p.V786I (on ENST00000343253 / NM_001306076.1; = p.V787I on NM_206886.4) | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs200030282, COSV58144492; called by muse, mutect2, varscan2
- CCL24 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs200038952, COSV56116247, COSV56116412; called by muse, mutect2, varscan2
- CFAP74 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs779154842, COSV54570853; called by muse, mutect2, varscan2
- CHL1 | c.3136C>T p.R1046C (on ENST00000397491 / NM_001253387.1; = p.R1062C on NM_006614.4) | Missense Mutation (SNP) | VAF 330/750 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs555557287, COSV56600202; called by muse, mutect2, varscan2
- CSMD3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 221/508 reads (44%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.967); catalogued as rs536561292, COSV52113015; called by muse, mutect2, varscan2
- CSRNP2 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.148); catalogued as rs745442348, COSV50398164; called by muse, mutect2, varscan2
- DCC | c.1850C>G p.T617R | Missense Mutation (SNP) | VAF 234/551 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59121633; called by muse, mutect2, varscan2
- DEFB104A | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs752842178, COSV100055431; called by mutect2, varscan2
- DEPDC5 | c.2497G>T p.E833* (on ENST00000400246; = p.E902* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 9/174 reads (5%) | catalogued as COSV56705198; called by muse, mutect2
- EGFR | c.1907G>A p.C636Y | Missense Mutation (SNP) | VAF 7852/8138 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51827490; called by muse, mutect2, varscan2
- EP400 | c.3095T>G p.L1032R | Missense Mutation (SNP) | VAF 207/445 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57780663; called by muse, mutect2, varscan2
- EPHX1 | c.400dup p.Q134Pfs*26 | Frame Shift Ins (INS) | VAF 17/158 reads (11%) | catalogued as rs756407271; called by mutect2, varscan2
- G3BP1 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 232/541 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV62366625; called by muse, mutect2, varscan2
- GAPDHS | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 64/122 reads (52%) | catalogued as COSV55882892; called by muse, mutect2, varscan2
- GRIA3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 514/554 reads (93%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs778052374, COSV52047915; called by muse, mutect2, varscan2
- HGF | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 536/1832 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs763933267, COSV55953843; called by muse, mutect2, varscan2
- IFNA21 | c.365G>C p.C122S | Missense Mutation (SNP) | VAF 575/635 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66518635; called by muse, mutect2, varscan2
- IL22 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 204/502 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1457566187, COSV60159830, COSV60160466; called by muse, mutect2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 33/286 reads (12%) | catalogued as rs745545309; called by mutect2, varscan2
- ITGB2 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56612095; called by muse, varscan2
- KCNC2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 412/830 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260222970, COSV54373037; called by muse, mutect2, varscan2
- KCNQ5 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 275/310 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs776285517, COSV59652775; called by muse, mutect2, varscan2
- KIAA1586 | c.768A>C p.L256F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV66057130; called by muse, mutect2, varscan2
- KIF1B | c.4544G>A p.R1515H (on ENST00000377086 / NM_001365952.1; = p.R1469H on NM_015074.3) | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs375130478; called by muse, mutect2, varscan2
- LONRF2 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 100/210 reads (48%) | catalogued as COSV66540302, COSV66540540; called by muse, mutect2, varscan2
- LOXL3 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.174); catalogued as rs765433257, COSV51210579; called by muse, mutect2, varscan2
- LRP1B | c.12773A>G p.Q4258R | Missense Mutation (SNP) | VAF 418/932 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.182); catalogued as COSV67253281; called by muse, varscan2
- LRP1B | c.12676A>G p.R4226G | Missense Mutation (SNP) | VAF 354/764 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as COSV67253283; called by muse, varscan2
- LRP1B | c.12117-2A>G p.X4039_splice | Splice Site (SNP) | VAF 372/837 reads (44%) | catalogued as COSV67253286; called by muse, mutect2, varscan2
- MAGEB1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 253/263 reads (96%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs750589796, COSV66776233; called by muse, mutect2, varscan2
- MDC1 | c.5436G>C p.K1812N | Missense Mutation (SNP) | VAF 142/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64526144; called by muse, mutect2, varscan2
- MUC16 | c.19499C>G p.T6500R | Missense Mutation (SNP) | VAF 238/516 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV67481243; called by muse, mutect2, varscan2
- MUC17 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 26/1041 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1016021456, COSV60287849; called by muse, mutect2
- MYH2 | c.4048C>T p.R1350W | Missense Mutation (SNP) | VAF 214/475 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776018379, COSV55430913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPD3 | c.2725dup p.Q909Pfs*12 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | catalogued as rs770284236; called by mutect2, varscan2
- NEK10 | c.2470G>A p.V824I | Missense Mutation (SNP) | VAF 905/1880 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs374938616; called by muse, mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- NOX3 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 88/97 reads (91%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV50158568; called by muse, mutect2, varscan2
- NOX4 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 176/348 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772044483, COSV54459911, COSV99632016; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 30/142 reads (21%) | catalogued as rs754860965; called by mutect2, varscan2
- OLR1 | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 386/763 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV58872306; called by muse, mutect2, varscan2
- OSER1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs759416435, COSV54854291; called by muse, mutect2, varscan2
- PCDHGC3 | c.2050dup p.R684Pfs*41 | Frame Shift Ins (INS) | VAF 12/105 reads (11%) | catalogued as rs764598056; called by mutect2, pindel, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 52/426 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PLSCR1 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 131/290 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61013367; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 76/529 reads (14%) | catalogued as rs778683789; called by mutect2, varscan2
- PROX2 | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV71520130; called by muse, mutect2, varscan2
- PTCHD3 | c.1436T>A p.M479K | Missense Mutation (SNP) | VAF 123/138 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV71257163; called by muse, mutect2, varscan2
- PTPRM | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 281/568 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV59872496; called by muse, mutect2, varscan2
- RIMS2 | c.2897G>A p.G966E (on ENST00000666250 / NM_001348490.2; = p.G774E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 378/882 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.883); catalogued as COSV51705234; called by muse, mutect2, varscan2
- S1PR3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as rs746355071, COSV63981022; called by muse, mutect2, varscan2
- SCN11A | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 202/488 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776207910, COSV56574685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC26A3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs745637222, COSV60641592; called by muse, mutect2, varscan2
- SNX24 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54454126; called by muse, mutect2, varscan2
- SVOPL | c.1186G>A p.G396S (on ENST00000419765; = p.G244S on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as rs144549446, COSV99939129; called by muse, mutect2, varscan2
- SYT9 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV59622556; called by muse, mutect2, varscan2
- TACSTD2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.071); catalogued as CM165837, COSV64667262; called by muse, mutect2, varscan2
- TMC2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV62656349; called by muse, mutect2, varscan2
- TMEM207 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 114/281 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.471); catalogued as COSV61562082; called by muse, mutect2, varscan2
- CNGA4 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 59/148 reads (40%) | called by muse, varscan2
- DEPDC5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/79 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GAPVD1 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 16/341 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- LPCAT1 | c.620C>A p.P207Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3CA | c.241_243del p.E81del | In Frame Del (DEL) | VAF 244/602 reads (41%) | called by pindel, varscan2
- SLC35A4 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- XKR6 | c.1572dup p.D525Rfs*3 | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | called by mutect2, pindel
- ABCG1 | c.1684C>T p.L562= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV59208251; called by muse, mutect2, varscan2
- CNKSR1 | c.186C>T p.G62= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs200570653; called by muse, mutect2, varscan2
- LRP4 | c.2790T>G p.A930= | Silent (SNP) | VAF 29/607 reads (5%) | catalogued as COSV66139211; called by muse, mutect2
- PCK1 | c.921C>T p.C307= | Silent (SNP) | VAF 103/366 reads (28%) | catalogued as rs758917878, COSV60128084; called by muse, mutect2, varscan2
- PRUNE2 | c.2046C>T p.S682= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- RIMBP2 | c.705C>T p.N235= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs768510767, COSV55463944, COSV55465866; called by muse, mutect2, varscan2
- SI | c.5370C>T p.N1790= | Silent (SNP) | VAF 524/1132 reads (46%) | catalogued as rs760411938, COSV52291316; called by muse, mutect2, varscan2
- ZNF18 | c.1023G>A p.E341= | Silent (SNP) | VAF 94/157 reads (60%) | catalogued as COSV59551013; called by mutect2, varscan2
- ZNF804B | c.1299C>A p.T433= | Silent (SNP) | VAF 191/596 reads (32%) | catalogued as COSV100306750, COSV60842777; called by muse, mutect2, varscan2
- KIR3DX1 | n.648A>T | RNA (SNP) | VAF 97/322 reads (30%) | catalogued as COSV99683675; called by muse, mutect2, varscan2
